MMRF case MMRF_2301 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/fce7e24d-9c33-4219-b024-84e1e86b88a6

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 62.1 years (22,681 days); ISS stage: II; Days to last known disease status: 765 days (2.1 years); Days to last follow up: 765 days (2.1 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -113 (ECOG 1): M Protein 1.08 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 80.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.69 mg/dL; Immunoglobulin G 25.7 g/L; Immunoglobulin A 1.07 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 4.26 µg/mL; Hemoglobin 7.19 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 285 ×10⁹/L; Creatinine 122 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 8.4 g/dL; Glucose 5.94 mmol/L.
- Day -24 (ECOG 1): M Protein 1.77 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 79.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.582 mg/dL; Immunoglobulin G 30.4 g/L; Immunoglobulin A 1.02 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.1 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 251 ×10⁹/L; Creatinine 125 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.5 mmol/L; Albumin 41 g/L; Total Protein 9.3 g/dL; Glucose 5.94 mmol/L.
- Day 71 (ECOG 1): M Protein 0.23 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.873 mg/dL; Immunoglobulin G 7.05 g/L; Immunoglobulin A 1.24 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 3.16 µg/mL; Hemoglobin 7.13 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 325 ×10⁹/L; Creatinine 110 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 6.4 g/dL; Glucose 6.77 mmol/L.
- Day 157: Serum Free Immunoglobulin Light Chain, Kappa 1.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.467 mg/dL; Immunoglobulin G 5.42 g/L; Immunoglobulin A 1.23 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 2.83 µg/mL; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 265 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 6.2 g/dL; Glucose 6 mmol/L.
- Day 276 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.913 mg/dL; Immunoglobulin G 7.94 g/L; Immunoglobulin A 1.76 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 2.81 µg/mL; Hemoglobin 7.5 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 279 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 6.9 g/dL; Glucose 6.27 mmol/L.
- Day 337 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Immunoglobulin G 7.95 g/L; Immunoglobulin A 2.14 g/L; Immunoglobulin M 0.41 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 279 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.43 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 6.44 mmol/L.
- Day 438 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.01 mg/dL; Beta 2 Microglobulin 3.33 µg/mL; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 298 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 6 g/dL; Glucose 6.16 mmol/L.
- Day 522: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.26 mg/dL; Immunoglobulin G 7.97 g/L; Immunoglobulin A 1.98 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 7.38 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 269 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.48 mmol/L; Albumin 41 g/L; Total Protein 6.6 g/dL; Glucose 5.89 mmol/L.
- Day 592: M Protein 0.14 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.61 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.52 mg/dL; Immunoglobulin G 9.73 g/L; Immunoglobulin A 2.52 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 318 ×10⁹/L; Creatinine 114 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 7.1 g/dL; Glucose 6 mmol/L.
- Day 681: M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.53 mg/dL; Immunoglobulin G 9.96 g/L; Immunoglobulin A 2.84 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 271 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 6.27 mmol/L.
- Day 765 (ECOG 1): M Protein 0.25 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.72 mg/dL; Immunoglobulin G 11.5 g/L; Immunoglobulin A 3.07 g/L; Immunoglobulin M 0.27 g/L; Hemoglobin 7.01 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 235 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.33 mmol/L; Albumin 37 g/L; Total Protein 6.7 g/dL; Glucose 6.71 mmol/L.

Other clinical attributes
- Day -113: Weight: 97 kg; Height: 180 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2301_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -113 days.
- Sample MMRF_2301_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -113 days.
